TCGA case TCGA-ZN-A9VP — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: Brigham and Women's Hospital Division of Thoracic Surgery. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/eb5a5b41-b493-408c-902e-c625f5ba7d2f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 51 years; Vital status: Alive.

Diagnoses (1)
1. Epithelioid mesothelioma, malignant: ICD-O-3 morphology code: 9052/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 51.2 years (18,697 days); Year of diagnosis: 2012; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 228 days.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Pemetrexed Disodium; Days to treatment start: 136 days; Days to treatment end: 228 days.
   Recorded as not given: Pleurodesis, NOS, prior to procurement; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 228 days; Disease response: Tumor Free.
- Imaging anatomic site: Pleura; Imaging suv max: 4.6; Timepoint: Prior to Treatment.
- Karnofsky performance status: 100; Timepoint: Preoperative.

Molecular and laboratory tests
- Creatinine 1.45 mg/dL [Blood test normal range lower: 0.5; Blood test normal range upper: 1.2].
- Serum Mesothelin 6.7 nmol/L [Blood test normal range lower: 0; Blood test normal range upper: 1.5].

Exposures
- Exposure type: Asbestos; Exposure source: Occupational.
- Occupation type: Other Clerical Support Workers.

Family history
- Relative with cancer history: yes; Relationship type: Parent; Relationship primary diagnosis: Lymphoma.
- Relative with cancer history: yes; Relationship type: Parent; Relationship primary diagnosis: Prostate Cancer.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-ZN-A9VP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 20 mg.
  Slide TCGA-ZN-A9VP-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-ZN-A9VP-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: Tumor free; History asbestos exposure: Yes; Primary occupation: Other, please specify; Occupation primary: UPS employee; New tumor event diagnosis indicator: No.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Epithelioid mesothelioma; Serum mesothelin prior treatment: 6.7.
- Follow-up form: Lost to follow-up: Yes.
- Drug treatment 2: Pharmaceutical therapy drug name: Alimta.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 228 days; disease-specific survival: no event (censored), 228 days; progression-free interval: no event (censored), 228 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-ZN-A9VP-01A-11D-A39Q-01): tumor purity 0.69, ploidy 2.13, whole-genome doublings 0.
